Somatic mutation profile of tumor specimen C3L-08267-01 (aliquot CPT0477770006) from CPTAC case C3L-08267, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 74.9 years (27,372 days).
Specimen C3L-08267-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Cardia; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b6e305e-f071-4a60-a65a-40e1c56a67c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08267-31 (Blood Derived Normal), aliquot CPT0475710003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3b6100e-f8a9-4094-8e6f-db56d3d93063

The open-access MAF lists 219 somatic variants for this specimen: 154 protein-altering or splice-affecting, 57 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 57, Nonsense Mutation 8, Intron 6, Frame Shift Del 3, Frame Shift Ins 2, Splice Region 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2744A>C p.K915T | Missense Mutation (SNP) | VAF 48/268 reads (18%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.98); catalogued as rs1234949048, COSV55945450, COSV55964424; called by muse, mutect2, varscan2
- ACLY | c.2461G>A p.V821M | Missense Mutation (SNP) | VAF 50/341 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1472750391; called by muse, mutect2, varscan2
- ADAMTS12 | c.2534G>A p.R845H | Missense Mutation (SNP) | VAF 63/339 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs551278824, COSV61256246; called by muse, mutect2, varscan2
- ADGRB1 | c.1567G>T p.G523C | Missense Mutation (SNP) | VAF 293/447 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100029548; called by muse, mutect2, varscan2
- AFF2 | c.2603A>C p.K868T | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV53975964, COSV53982508; called by muse, mutect2, varscan2
- ANKRD27 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 210/470 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs558381081; called by muse, mutect2, varscan2
- ARHGAP28 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 129/368 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs753094289, COSV51630963; called by muse, mutect2, varscan2
- BRD2 | c.1579C>T p.L527F | Missense Mutation (SNP) | VAF 69/417 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as rs773521318; called by muse, mutect2, varscan2
- BTBD11 | c.2346G>T p.L782F (on ENST00000280758 / NM_001018072.2; = p.L319F on NM_001017523.2) | Missense Mutation (SNP) | VAF 216/442 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs748100369, COSV55020794; called by mutect2, varscan2
- CACNA1E | c.4226T>G p.V1409G | Missense Mutation (SNP) | VAF 141/394 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100702474; called by muse, mutect2, varscan2
- CFAP161 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.093); catalogued as rs765921742, COSV54429190; called by muse, mutect2
- CFAP299 | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 79/271 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV63887267; called by muse, mutect2, varscan2
- CHST4 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 110/599 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs145030566, COSV58297622; called by muse, mutect2, varscan2
- CNTNAP5 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1455891898, COSV70476949; called by muse, mutect2, varscan2
- CPB1 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 88/416 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs142211299; called by muse, mutect2, varscan2
- CPS1 | c.3266G>A p.R1089H | Missense Mutation (SNP) | VAF 159/444 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1280211937, CM063923, COSV51805355; called by muse, mutect2, varscan2
- CTNND2 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 73/361 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as rs777721558; called by muse, mutect2, varscan2
- DDI1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 234/582 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1232741918, COSV100161319; called by muse, mutect2, varscan2
- DIP2B | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 41/199 reads (21%) | catalogued as COSV99998576; called by muse, mutect2, varscan2
- DLX5 | c.360A>C p.K120N | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs752314719; called by muse, mutect2, varscan2
- DNAH14 | c.3085A>C p.S1029R (on ENST00000445597; = p.S1413R on NM_001367479.1) | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV60741578; called by muse, mutect2, varscan2
- DSEL | c.430T>G p.L144V | Missense Mutation (SNP) | VAF 120/328 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100026222; called by muse, mutect2, varscan2
- E2F8 | c.2338G>C p.G780R | Missense Mutation (SNP) | VAF 69/570 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs765067923; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.47G>C p.R16P | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as COSV61080041, COSV61080329; called by muse, mutect2, varscan2
- EPHA6 | c.1606+4A>G | Splice Region (SNP) | VAF 64/329 reads (19%) | catalogued as COSV67559379; called by muse, mutect2, varscan2
- EPHA7 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs1484017296, COSV65189826; called by muse, mutect2, varscan2
- ERCC2 | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 158/360 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs751318902, COSV67270315; called by muse, mutect2, varscan2
- F13A1 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 69/449 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV99343286; called by muse, mutect2, varscan2
- FAT4 | c.13009T>G p.F4337V | Missense Mutation (SNP) | VAF 99/281 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58708247; called by muse, mutect2, varscan2
- FIGN | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 97/476 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60763321; called by muse, mutect2, varscan2
- FJX1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 199/515 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58553131; called by muse, mutect2, varscan2
- FSIP2 | c.10165dup p.I3389Nfs*6 | Frame Shift Ins (INS) | VAF 40/203 reads (20%) | catalogued as rs1559030497; called by mutect2, varscan2
- GRHL1 | c.1251C>G p.I417M | Missense Mutation (SNP) | VAF 88/424 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV61406305; called by muse, mutect2
- HBG2 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.148); catalogued as rs1333574834; called by muse, mutect2, varscan2
- HES6 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 231/631 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.164); catalogued as COSV99612714; called by muse, mutect2, varscan2
- IGHV3-16 | c.142T>G p.F48V | Missense Mutation (SNP) | VAF 95/546 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs782185870; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.871G>A p.E291K (on ENST00000485419 / NM_001197113.1; = p.E215K on NM_014575.3) | Missense Mutation (SNP) | VAF 90/392 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs1199973797; called by muse, mutect2, varscan2
- KCNK2 | c.12C>A p.S4R | Missense Mutation (SNP) | VAF 153/351 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs763863451; called by muse, mutect2, varscan2
- LRRIQ1 | c.681A>G p.Q227= | Splice Region (SNP) | VAF 47/110 reads (43%) | catalogued as rs781580490; called by muse, mutect2, varscan2
- MACF1 | c.20159G>A p.R6720Q (on ENST00000372915; = p.R4765Q on NM_012090.5) | Missense Mutation (SNP) | VAF 152/506 reads (30%) | catalogued as rs750406867, COSV57113661; called by muse, mutect2, varscan2
- MALRD1 | c.2026C>T p.R676W | Missense Mutation (SNP) | VAF 117/314 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs183995463; called by muse, mutect2, varscan2
- MCF2 | c.70T>G p.L24V | Missense Mutation (SNP) | VAF 107/191 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58476896, COSV58478333; called by muse, mutect2, varscan2
- MOS | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.269); catalogued as COSV61336538; called by muse, varscan2
- MS4A7 | c.51G>T p.K17N | Missense Mutation (SNP) | VAF 39/268 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV55728606; called by muse, mutect2, varscan2
- NELL1 | c.1020A>C p.K340N | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.787); catalogued as COSV54236708, COSV54263958; called by muse, mutect2, varscan2
- NYAP2 | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 116/347 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as rs368954224; called by muse, mutect2, varscan2
- OLFM3 | c.255A>C p.Q85H (on ENST00000338858 / NM_001288821.1; = p.Q65H on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100128821; called by muse, mutect2, varscan2
- OR10G2 | c.628G>T p.V210L | Missense Mutation (SNP) | VAF 136/577 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.045); catalogued as rs1341875443; called by muse, mutect2
- OR10G4 | c.406A>G p.S136G | Missense Mutation (SNP) | VAF 64/832 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100304802; called by muse, mutect2
- OR52B6 | c.721C>A p.L241I | Missense Mutation (SNP) | VAF 137/372 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV61448098; called by mutect2, varscan2
- OR6T1 | c.947T>C p.L316P | Missense Mutation (SNP) | VAF 117/330 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.233); catalogued as COSV58306488, COSV58309678; called by muse, mutect2, varscan2
- OR7E24 | c.404T>A p.V135E | Missense Mutation (SNP) | VAF 109/388 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs375162747; called by muse, mutect2, varscan2
- OR8U1 | c.542A>T p.D181V | Missense Mutation (SNP) | VAF 77/473 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV56415476; called by muse, mutect2, varscan2
- PCDH9 | c.77T>G p.L26R | Missense Mutation (SNP) | VAF 124/278 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.085); catalogued as COSV60532834; called by muse, mutect2, varscan2
- PCLO | c.12814C>T p.R4272C | Missense Mutation (SNP) | VAF 112/342 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs373739483; called by muse, mutect2, varscan2
- PLPP6 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 190/467 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs755269993; called by muse, mutect2, varscan2
- PREX2 | c.4357T>G p.L1453V | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV99907285; called by muse, mutect2, varscan2
- RBM41 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 61/162 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs764608753; called by muse, mutect2, varscan2
- RIMS1 | c.649C>T p.R217W | Missense Mutation (SNP) | VAF 119/361 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs185303689, COSV53436998, COSV99325850; called by muse, mutect2, varscan2
- RNF123 | c.1300G>A p.V434I | Missense Mutation (SNP) | VAF 55/285 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs751933046, COSV100570982, COSV59686785; called by muse, varscan2
- RNF38 | c.1183A>G p.M395V | Missense Mutation (SNP) | VAF 108/270 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs771141402; called by muse, mutect2, varscan2
- ROBO1 | c.485C>G p.S162W | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71393849; called by muse, mutect2, varscan2
- RPEL1 | c.365G>A p.G122E | Missense Mutation (SNP) | VAF 89/458 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.664); catalogued as COSV101483081; called by muse, mutect2, varscan2
- SATB2 | c.2158G>A p.A720T | Missense Mutation (SNP) | VAF 114/345 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53477852; called by muse, mutect2, varscan2
- SCN9A | c.3550A>C p.T1184P (on ENST00000303354; = p.T1173P on NM_002977.3) | Missense Mutation (SNP) | VAF 64/364 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57602015; called by muse, mutect2, varscan2
- SDK1 | c.3230T>G p.V1077G | Missense Mutation (SNP) | VAF 71/353 reads (20%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.843); catalogued as rs1327124953; called by muse, mutect2, varscan2
- SERPINA7 | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV59666388; called by muse, mutect2, varscan2
- SYNGAP1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 221/612 reads (36%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.977); catalogued as rs772336493, COSV53381040; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLR4 | c.1492T>A p.L498M (on ENST00000355622 / NM_138554.5; = p.L458M on NM_003266.4) | Missense Mutation (SNP) | VAF 110/264 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923526; called by muse, mutect2, varscan2
- TMEM132B | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 146/342 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV54750873; called by muse, mutect2, varscan2
- TRPM6 | c.3617G>A p.S1206N | Missense Mutation (SNP) | VAF 140/351 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as rs751907336; called by muse, mutect2, varscan2
- TSPYL6 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 165/478 reads (35%) | catalogued as rs565597661; called by muse, mutect2, varscan2
- TTN | c.87748G>A p.E29250K (on ENST00000591111; = p.E21826K on NM_003319.4) | Missense Mutation (SNP) | VAF 65/361 reads (18%) | PolyPhen benign (0.311); catalogued as COSV59997982; called by muse, mutect2, varscan2
- TUBB1 | c.653C>T p.T218M | Missense Mutation (SNP) | VAF 147/609 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.023); catalogued as rs539171911, COSV53887306; called by muse, mutect2, varscan2
- UNC5CL | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 150/374 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs978862845; called by muse, mutect2, varscan2
- USP24 | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 103/298 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs985517176; called by muse, mutect2, varscan2
- ZBTB20 | c.529G>A p.A177T (on ENST00000474710 / NM_001164342.2; = p.A104T on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/361 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100614271; called by muse, mutect2, varscan2
- ZNF2 | c.509G>A p.R170Q (on ENST00000611147 / NM_001291605.2; = p.R157Q on NM_021088.4) | Missense Mutation (SNP) | VAF 86/506 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as rs750115077, COSV54636577; called by muse, mutect2, varscan2
- ZNF219 | c.824G>A p.R275H | Missense Mutation (SNP) | VAF 127/883 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1314927181; called by muse, mutect2, varscan2
- ZNF362 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 32/886 reads (4%) | SIFT tolerated (0.71); PolyPhen benign (0.085); catalogued as COSV65031980; called by muse, mutect2
- ZNF43 | c.2006A>G p.K669R | Missense Mutation (SNP) | VAF 44/226 reads (19%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.959); catalogued as COSV61682619, COSV61685077; called by muse, mutect2, varscan2
- ZNF707 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 112/871 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.756); catalogued as rs569187572, COSV62310955; called by muse, mutect2, varscan2
- ZNF804A | c.2635C>G p.L879V | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.021); catalogued as COSV56445226; called by muse, mutect2, varscan2
- ACSM4 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS16 | c.3628T>G p.F1210V | Missense Mutation (SNP) | VAF 92/362 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ANKRD30A | c.683A>C p.N228T (on ENST00000611781; = p.N172T on NM_052997.2) | Missense Mutation (SNP) | VAF 102/241 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- B3GNT7 | c.887_897del p.P296Rfs*81 | Frame Shift Del (DEL) | VAF 87/516 reads (17%) | called by mutect2, pindel, varscan2
- BPTF | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 107/316 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- CATSPERB | c.1573A>G p.N525D | Missense Mutation (SNP) | VAF 54/418 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH24 | c.2414G>A p.R805H | Missense Mutation (SNP) | VAF 268/561 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CNTNAP5 | c.452T>G p.F151C | Missense Mutation (SNP) | VAF 134/438 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DCAF15 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 76/353 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DCP1A | c.1466T>C p.L489P | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- DCSTAMP | c.354T>G p.F118L | Missense Mutation (SNP) | VAF 282/438 reads (64%) | SIFT tolerated (1); PolyPhen benign (0.001); called by mutect2, varscan2
- DGKI | c.1373T>C p.V458A | Missense Mutation (SNP) | VAF 191/390 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- DPH3 | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 59/413 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- EIF2AK1 | c.1643C>A p.S548Y | Missense Mutation (SNP) | VAF 125/375 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- ELK1 | c.943A>T p.K315* | Nonsense Mutation (SNP) | VAF 161/304 reads (53%) | called by muse, mutect2, varscan2
- EPHA3 | c.2272T>G p.L758V | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EPHA8 | c.378C>A p.Y126* | Nonsense Mutation (SNP) | VAF 228/489 reads (47%) | called by muse, mutect2, varscan2
- FAM161B | c.2105C>T p.S702L (on ENST00000651776; = p.S639L on NM_152445.3) | Missense Mutation (SNP) | VAF 202/425 reads (48%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAT3 | c.3166T>C p.S1056P | Missense Mutation (SNP) | VAF 52/380 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- GABRA4 | c.122A>G p.E41G | Missense Mutation (SNP) | VAF 122/275 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GNGT1 | c.58G>C p.D20H | Missense Mutation (SNP) | VAF 40/297 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- GRM7 | c.2063A>C p.K688T | Missense Mutation (SNP) | VAF 69/328 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GSAP | c.1456C>G p.L486V | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.103); called by muse, mutect2
- GSTA4 | c.27T>A p.Y9* | Nonsense Mutation (SNP) | VAF 77/449 reads (17%) | called by muse, mutect2, varscan2
- HCN1 | c.1530A>C p.K510N | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- IGLJ3 | c.11G>T p.C4F | Missense Mutation (SNP) | VAF 114/786 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); called by mutect2, varscan2
- IGSF10 | c.3348A>C p.K1116N | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- JHY | c.2215A>C p.N739H | Missense Mutation (SNP) | VAF 46/370 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KMT2A | c.3241C>T p.R1081* | Nonsense Mutation (SNP) | VAF 134/459 reads (29%) | called by muse, mutect2, varscan2
- MAP3K15 | c.1110C>A p.D370E | Missense Mutation (SNP) | VAF 69/184 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MATN1 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 210/678 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.375); called by muse, mutect2, varscan2
- MED6 | c.542T>G p.L181R | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MKI67 | c.4375G>A p.E1459K | Missense Mutation (SNP) | VAF 81/436 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MUC16 | c.16894T>A p.F5632I | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MYOM3 | c.3320C>T p.A1107V | Missense Mutation (SNP) | VAF 138/305 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- NAALADL2 | c.793G>C p.A265P | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NEB | c.2170C>T p.Q724* | Nonsense Mutation (SNP) | VAF 22/188 reads (12%) | called by muse, mutect2, varscan2
- NME8 | c.934A>G p.S312G | Missense Mutation (SNP) | VAF 70/240 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G9 | c.406A>G p.S136G | Missense Mutation (SNP) | VAF 94/276 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- OR4K17 | c.662T>A p.I221N | Missense Mutation (SNP) | VAF 68/488 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR4S2 | c.685_686insTC p.E229Vfs*53 | Frame Shift Ins (INS) | VAF 85/519 reads (16%) | called by mutect2, varscan2*
- OR4S2 | c.687_688del p.G230Qfs*30 | Frame Shift Del (DEL) | VAF 86/534 reads (16%) | called by mutect2, varscan2*
- OR5T2 | c.721T>G p.F241V | Missense Mutation (SNP) | VAF 117/362 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PDAP1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 94/298 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PIK3C2B | c.2518T>A p.W840R | Missense Mutation (SNP) | VAF 167/356 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- PLXNA4 | c.5674T>G p.L1892V | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.013); called by muse, mutect2
- POM121C | c.26G>C p.G9A | Missense Mutation (SNP) | VAF 175/634 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAG1 | c.1051T>A p.L351M | Missense Mutation (SNP) | VAF 129/393 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAPGEF4 | c.789A>C p.Q263H | Missense Mutation (SNP) | VAF 147/423 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAGE1 | c.191G>C p.S64T | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- SAMD4A | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 53/438 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAMSN1 | c.203A>C p.K68T | Missense Mutation (SNP) | VAF 91/298 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SECISBP2L | c.2125C>A p.P709T (on ENST00000559471 / NM_001193489.2; = p.P664T on NM_014701.4) | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEMA3F | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 73/396 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- SEMA5A | c.2139G>A p.W713* | Nonsense Mutation (SNP) | VAF 168/482 reads (35%) | called by muse, mutect2, varscan2
- SPANXN4 | c.160T>A p.F54I | Missense Mutation (SNP) | VAF 115/191 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.482); called by muse, mutect2, varscan2
- SVIL | c.5984del p.G1995Efs*119 (on ENST00000355867 / NM_021738.3; = p.G1569Efs*119 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 88/252 reads (35%) | called by mutect2, pindel, varscan2
- SYNE1 | c.16454A>C p.K5485T (on ENST00000367255 / NM_182961.4; = p.K5414T on NM_033071.3) | Missense Mutation (SNP) | VAF 123/346 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX15 | c.3745G>A p.G1249S (on ENST00000256246; = p.G1632S on NM_001350162.2) | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- THSD7B | c.2800T>C p.W934R | Missense Mutation (SNP) | VAF 114/400 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TMEM60 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- TMF1 | c.2085A>C p.E695D | Missense Mutation (SNP) | VAF 75/317 reads (24%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); called by muse, mutect2, varscan2
- TMPRSS11F | c.213A>C p.K71N | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMPRSS15 | c.799C>A p.L267M | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- UGGT2 | c.232A>C p.K78Q | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- WDR6 | c.1169T>C p.F390S | Missense Mutation (SNP) | VAF 88/373 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- WNK2 | c.4571G>A p.G1524E (on ENST00000297954 / NM_001282394.1; = p.G1487E on NM_006648.3) | Missense Mutation (SNP) | VAF 242/527 reads (46%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF587 | c.1286T>C p.L429P | Missense Mutation (SNP) | VAF 144/453 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- ZNF606 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ZNF679 | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 72/306 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.243); called by mutect2, varscan2
- ZNF737 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ABCB1 | c.2445T>C p.T815= | Silent (SNP) | VAF 69/335 reads (21%) | called by muse, mutect2, varscan2
- ASTN1 | c.291A>C p.S97= | Silent (SNP) | VAF 82/221 reads (37%) | called by muse, mutect2, varscan2
- BCAR1 | c.2604A>G p.A868= | Silent (SNP) | VAF 108/398 reads (27%) | called by muse, varscan2
- C1QL2 | c.117G>A p.A39= | Silent (SNP) | VAF 86/581 reads (15%) | catalogued as rs904193888; called by muse, mutect2, varscan2
- C3orf84 | c.153G>A p.Q51= | Silent (SNP) | VAF 97/334 reads (29%) | catalogued as rs914241180; called by muse, mutect2, varscan2
- CILP2 | c.567G>A p.Q189= | Silent (SNP) | VAF 126/567 reads (22%) | called by muse, mutect2, varscan2
- CNBD2 | c.1491T>C p.F497= (on ENST00000373973 / NM_001365709.1; = p.F493= on NM_080834.4) | Silent (SNP) | VAF 128/633 reads (20%) | catalogued as rs190654792; called by muse, mutect2, varscan2
- COL6A6 | c.432G>A p.E144= | Silent (SNP) | VAF 74/323 reads (23%) | catalogued as rs1347677287; called by muse, mutect2, varscan2
- CWH43 | c.1275C>G p.T425= | Silent (SNP) | VAF 70/218 reads (32%) | called by muse, mutect2, varscan2
- DHX15 | c.972T>C p.T324= | Silent (SNP) | VAF 101/223 reads (45%) | called by muse, mutect2, varscan2
- EFCAB8 | c.2964G>A p.T988= | Silent (SNP) | VAF 179/391 reads (46%) | catalogued as rs1334471987, COSV101503640; called by muse, mutect2, varscan2
- EPS15 | c.324T>C p.S108= | Silent (SNP) | VAF 92/271 reads (34%) | called by muse, mutect2, varscan2
- F13B | c.1116A>G p.G372= | Silent (SNP) | VAF 94/267 reads (35%) | called by muse, mutect2, varscan2
- FJX1 | c.126C>T p.P42= | Silent (SNP) | VAF 38/292 reads (13%) | called by muse, varscan2
- FOXL2 | c.363C>T p.G121= | Silent (SNP) | VAF 92/464 reads (20%) | called by muse, mutect2, varscan2
- GCK | c.675C>T p.I225= | Silent (SNP) | VAF 51/196 reads (26%) | catalogued as rs772754004, CM012125, COSV60786489; called by muse, mutect2, varscan2
- GLA | c.1161C>T p.L387= | Silent (SNP) | VAF 119/241 reads (49%) | catalogued as CX141656; called by muse, mutect2, varscan2
- GRM5 | c.598A>C p.R200= | Silent (SNP) | VAF 105/349 reads (30%) | called by muse, mutect2, varscan2
- GRM8 | c.216G>C p.G72= | Silent (SNP) | VAF 148/370 reads (40%) | called by muse, mutect2, varscan2
- HERC2 | c.5163G>T p.P1721= | Silent (SNP) | VAF 14/402 reads (3%) | catalogued as rs1374032833, COSV55323808; called by muse, mutect2
- IGHV1-2 | c.324C>T p.D108= | Silent (SNP) | VAF 10/320 reads (3%) | catalogued as rs1061869; called by muse, mutect2
- IRF2BPL | c.414G>A p.A138= | Silent (SNP) | VAF 80/514 reads (16%) | called by muse, varscan2
- KANK4 | c.1065G>A p.E355= | Silent (SNP) | VAF 174/483 reads (36%) | catalogued as rs1557489313; called by muse, mutect2, varscan2
- KCNH4 | c.2766T>A p.A922= | Silent (SNP) | VAF 144/684 reads (21%) | catalogued as COSV99236814; called by muse, mutect2, varscan2
- KRTAP12-3 | c.204C>A p.P68= | Silent (SNP) | VAF 111/334 reads (33%) | called by mutect2, varscan2
- LAMA2 | c.4812G>A p.A1604= | Silent (SNP) | VAF 63/392 reads (16%) | catalogued as rs756024063; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMA5 | c.7842G>A p.A2614= | Silent (SNP) | VAF 113/536 reads (21%) | catalogued as rs770413191, COSV53363157; called by muse, mutect2, varscan2
- LAMA5 | c.1938G>A p.A646= | Silent (SNP) | VAF 83/758 reads (11%) | catalogued as rs766890003, COSV99440212; called by muse, varscan2
- LINGO1 | c.1311C>T p.D437= | Silent (SNP) | VAF 84/538 reads (16%) | catalogued as rs369123579; called by muse, varscan2
- MAP9 | c.27T>C p.T9= | Silent (SNP) | VAF 54/154 reads (35%) | called by muse, mutect2, varscan2
- MRPS12 | c.72C>G p.L24= | Silent (SNP) | VAF 150/333 reads (45%) | catalogued as COSV55501884; called by muse, mutect2, varscan2
- NAT10 | c.1350G>A p.T450= | Silent (SNP) | VAF 91/286 reads (32%) | catalogued as rs1247578526; called by muse, varscan2
- NCAM1 | c.1794C>T p.S598= (on ENST00000316851 / NM_181351.5; = p.S588= on NM_000615.7) | Silent (SNP) | VAF 67/372 reads (18%) | catalogued as rs199567425; called by muse, varscan2
- NPAP1 | c.444G>A p.E148= | Silent (SNP) | VAF 91/319 reads (29%) | catalogued as rs745650476, COSV61509817; called by muse, mutect2, varscan2
- NXPH1 | c.417G>C p.G139= | Silent (SNP) | VAF 42/468 reads (9%) | called by muse, mutect2
- OR13H1 | c.552T>A p.I184= | Silent (SNP) | VAF 65/285 reads (23%) | called by muse, mutect2, varscan2
- OR4K17 | c.663C>A p.I221= | Silent (SNP) | VAF 67/482 reads (14%) | called by muse, mutect2, varscan2
- OR5M10 | c.495C>T p.H165= | Silent (SNP) | VAF 22/481 reads (5%) | called by muse, mutect2
- OR6C1 | c.231C>G p.P77= | Silent (SNP) | VAF 75/209 reads (36%) | called by muse, mutect2, varscan2
- PARM1 | c.687G>T p.V229= | Silent (SNP) | VAF 180/597 reads (30%) | called by muse, mutect2, varscan2
- PCDH8 | c.1329C>T p.Y443= | Silent (SNP) | VAF 235/484 reads (49%) | called by muse, mutect2, varscan2
- PXDNL | c.4359A>G p.R1453= | Silent (SNP) | VAF 40/190 reads (21%) | called by muse, mutect2, varscan2
- RALYL | c.816T>C p.D272= | Silent (SNP) | VAF 22/458 reads (5%) | catalogued as rs1446745968; called by muse, mutect2
- RIMS2 | c.1269T>C p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 265/404 reads (66%) | catalogued as rs778061023, COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2, varscan2
- SALL3 | c.429C>T p.R143= | Silent (SNP) | VAF 192/464 reads (41%) | catalogued as rs1467425547, COSV73306407; called by muse, mutect2, varscan2
- SGK1 | c.435G>A p.S145= | Silent (SNP) | VAF 28/330 reads (8%) | catalogued as rs146022654, COSV52815222; called by muse, mutect2
- SLC24A2 | c.402G>T p.A134= | Silent (SNP) | VAF 102/264 reads (39%) | catalogued as rs757158542; called by muse, mutect2, varscan2
- SYNM | c.2751T>C p.H917= | Silent (SNP) | VAF 97/545 reads (18%) | catalogued as rs782031441; called by muse, mutect2, varscan2
- TBC1D14 | c.411G>A p.S137= | Silent (SNP) | VAF 106/474 reads (22%) | catalogued as rs746160356, COSV68987204; called by muse, mutect2, varscan2
- TMEM108 | c.66C>T p.T22= | Silent (SNP) | VAF 48/254 reads (19%) | catalogued as rs182516650, COSV58878378; called by muse, mutect2, varscan2
- TRAFD1 | c.951C>T p.A317= | Silent (SNP) | VAF 92/233 reads (39%) | called by muse, mutect2, varscan2
- TUSC3 | c.516A>T p.G172= | Silent (SNP) | VAF 34/183 reads (19%) | called by muse, mutect2, varscan2
- VPS52 | c.193C>T p.L65= | Silent (SNP) | VAF 64/453 reads (14%) | called by muse, mutect2, varscan2
- WASF3 | c.1428G>A p.T476= | Silent (SNP) | VAF 75/346 reads (22%) | catalogued as rs146613276; called by muse, mutect2, varscan2
- ZIM2 | c.1149T>A p.T383= | Silent (SNP) | VAF 137/443 reads (31%) | catalogued as rs568187266, COSV55633455; called by muse, mutect2, varscan2
- ZNF257 | c.1458C>G p.P486= | Silent (SNP) | VAF 59/234 reads (25%) | catalogued as rs925200079, COSV71306369; called by muse, mutect2, varscan2
- ZNF714 | c.36C>T p.V12= | Silent (SNP) | VAF 67/228 reads (29%) | catalogued as COSV52512547; called by muse, mutect2, varscan2
- ABCA8 | c.1789-301T>G | Intron (SNP) | VAF 103/276 reads (37%) | catalogued as rs1365363628; called by muse, mutect2, varscan2
- CDH11 | c.1895-641T>G | Intron (SNP) | VAF 96/319 reads (30%) | called by muse, mutect2, varscan2
- MAFB | c.*840C>T | 3'UTR (SNP) | VAF 167/695 reads (24%) | catalogued as rs777476019; called by muse, mutect2, varscan2
- MAGEC3 | c.1124-200C>T | Intron (SNP) | VAF 14/342 reads (4%) | called by muse, mutect2
- OAS2 | c.448+32_448+37dup | Intron (INS) | VAF 122/321 reads (38%) | called by mutect2, varscan2
- RBM43 | c.3+341C>G | Intron (SNP) | VAF 16/528 reads (3%) | called by muse, mutect2
- SLC22A8 | c.1530-30C>A | Intron (SNP) | VAF 243/650 reads (37%) | catalogued as COSV100268158; called by muse, mutect2, varscan2
- SUCO | chr1:172532485 T>C | 5'Flank (SNP) | VAF 115/273 reads (42%) | catalogued as COSV99041141; called by muse, mutect2, varscan2
